Somatic mutation profile of tumor specimen b873f54a-5a86-4dca-90f9-715820 (aliquot b873f54a-5a86-4dca-90f9-715820_D6) from CPTAC case 01CO015, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen b873f54a-5a86-4dca-90f9-715820: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ce33a82-4975-4201-9c3f-63ea46e5183e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 3ac1f563-df29-48cd-ac47-86cd34 (Blood Derived Normal), aliquot 3ac1f563-df29-48cd-ac47-86cd34_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bec38db-090d-40d8-a04c-86dcfc0636c1

The open-access MAF lists 149 somatic variants for this specimen: 95 protein-altering or splice-affecting, 39 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 39, Intron 8, Nonsense Mutation 6, Splice Region 4, Splice Site 4, Frame Shift Del 3, 5'UTR 3, Frame Shift Ins 2, 3'UTR 2, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.901+1G>C p.X301_splice | Splice Site (SNP) | VAF 46/113 reads (41%) | catalogued as rs748840480, CS031764; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DES | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913003, CM000368; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARD | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100991865; called by muse, mutect2, varscan2
- ADAMTS2 | c.3116G>A p.S1039N | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs771197106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER3 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as rs555917912, COSV58466667; called by muse, mutect2, varscan2
- APC | c.4460del p.T1487Ifs*20 | Frame Shift Del (DEL) | VAF 32/67 reads (48%) | catalogued as COSV57346896; called by mutect2, pindel*, varscan2
- AQP7 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs371783551; called by muse, mutect2, varscan2
- ARFGAP1 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 34/456 reads (7%) | catalogued as rs779759799; called by muse, mutect2
- ARGFX | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs927281188; called by muse, mutect2, varscan2
- ASB18 | c.206-5C>T | Splice Region (SNP) | VAF 178/290 reads (61%) | catalogued as rs980857244, COSV58232262, COSV58232519; called by mutect2, varscan2
- CAMTA1 | c.2431C>T p.R811W | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57928764; called by muse, mutect2, varscan2
- CERS3 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs373080717, COSV52565917; called by muse, mutect2, varscan2
- CFAP47 | c.8006C>T p.T2669M | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1431557641, COSV66216748; called by muse, mutect2, varscan2
- CHD4 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1254024057, COSV58899332; called by muse, mutect2, varscan2
- CIB2 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.268); catalogued as rs1247582322; called by muse, mutect2, varscan2
- CNKSR1 | c.1864C>T p.R622C (on ENST00000374253 / NM_001297647.2; = p.R615C on NM_006314.3) | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs771252222; called by muse, mutect2, varscan2
- COL12A1 | c.3080G>A p.R1027H | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs79863717, COSV59391190; called by muse, mutect2, varscan2
- CTSH | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs765453077; called by muse, mutect2, varscan2
- CYP27B1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 228/529 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV99141509; called by muse, mutect2, varscan2
- DAPK1 | c.1378G>A p.V460M | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200758451, COSV63790671; called by muse, mutect2, varscan2
- DCAF12L1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV64422471; called by muse, mutect2, varscan2
- DMRTA2 | c.1468G>A p.G490S | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777814885; called by muse, mutect2, varscan2
- DNAH11 | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs202234068, COSV60952972; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENPP2 | c.2347G>A p.D783N (on ENST00000075322 / NM_001040092.3; = p.D835N on NM_006209.5) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.707); catalogued as rs201911203, COSV50016383; called by muse, mutect2
- EPHA6 | c.378C>A p.N126K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs757309852; called by muse, mutect2, varscan2
- FOXL1 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs769689778; called by muse, mutect2, varscan2
- GABRB3 | c.296A>C p.Y99S | Missense Mutation (SNP) | VAF 90/167 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV54688097; called by muse, mutect2, varscan2
- GCKR | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 166/271 reads (61%) | catalogued as rs201754753; called by muse, mutect2, varscan2
- GRIA2 | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 125/282 reads (44%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as COSV52384331; called by mutect2, varscan2
- GRID2IP | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as rs776704918; called by muse, mutect2, varscan2
- GRIP2 | c.311G>A p.R104Q (on ENST00000619221; = p.R7Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.3); catalogued as rs766011095, COSV56124881; called by muse, mutect2, varscan2
- INTS9 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.111); catalogued as rs532323381; called by muse, mutect2, varscan2
- KCNT2 | c.2866A>T p.I956F | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs377580548; called by muse, mutect2, varscan2
- KIAA0232 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as rs200418556; called by muse, mutect2, varscan2
- KRTAP4-16 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 60/422 reads (14%) | SIFT deleterious (0.01); catalogued as rs751900716; called by muse, mutect2, varscan2
- LMNTD2 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs774615777; called by muse, mutect2, varscan2
- LRRC30 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 88/151 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs368607621; called by muse, mutect2, varscan2
- MAP3K21 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100786191; called by muse, mutect2, varscan2
- MROH2B | c.4135C>T p.R1379* | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | catalogued as COSV101270554; called by muse, mutect2, varscan2
- MYO10 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs1180595906; called by muse, mutect2, varscan2
- MYT1L | c.2999C>T p.T1000M | Missense Mutation (SNP) | VAF 181/324 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs775126278, COSV67701362, COSV67702261; called by muse, mutect2, varscan2
- NOTCH4 | c.4475G>A p.R1492Q | Missense Mutation (SNP) | VAF 78/126 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs761314959, COSV66679639; called by muse, mutect2, varscan2
- OVCH1 | c.2866G>T p.V956F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1288925868; called by muse, mutect2
- PCLO | c.4088C>T p.T1363M | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370195239, COSV61617158; called by muse, mutect2, varscan2
- PROM2 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs777226405; called by muse, mutect2, varscan2
- RUNX1T1 | c.1092A>G p.I364M (on ENST00000265814 / NM_001198628.1; = p.I337M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224173133, COSV56165963; called by muse, mutect2, varscan2
- SFMBT2 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374674288; called by muse, mutect2, varscan2
- SLC27A4 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 133/510 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774589847; called by muse, mutect2, varscan2
- SRA1 | c.61+4A>G | Splice Region (SNP) | VAF 68/146 reads (47%) | catalogued as rs1342297316; called by muse, mutect2, varscan2
- STX10 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs144491920, COSV104387087; called by muse, mutect2, varscan2
- TF | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs528945191, COSV53918325; called by muse, mutect2, varscan2
- TRANK1 | c.8254G>A p.E2752K | Missense Mutation (SNP) | VAF 124/364 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV57147380, COSV57152147; called by muse, mutect2, varscan2
- TRPC3 | c.331G>A p.A111T (on ENST00000379645 / NM_001366479.2; = p.A38T on NM_003305.2) | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs200365791, COSV99313685; called by muse, mutect2, varscan2
- UBAP2L | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV55177317; called by muse, mutect2, varscan2
- VPS28 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.295); catalogued as rs139498764; called by muse, mutect2, varscan2
- ZIC1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.085); catalogued as COSV99292049; called by muse, mutect2, varscan2
- ABCC8 | c.1730T>C p.F577S | Missense Mutation (SNP) | VAF 198/397 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- AC138647.1 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACSS3 | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- ARHGAP22 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- BPIFB2 | c.577+1G>A p.X193_splice | Splice Site (SNP) | VAF 25/346 reads (7%) | called by muse, mutect2
- CCNK | c.1735A>G p.M579V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2
- CLEC1B | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, varscan2
- DDN | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKZ | c.933G>A p.L311= (on ENST00000454345 / NM_001105540.2; = p.L122= on NM_003646.4) | Splice Region (SNP) | VAF 61/243 reads (25%) | called by muse, mutect2, varscan2
- DMXL1 | c.7864-1G>A p.X2622_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- DRC7 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 61/386 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- E2F7 | c.2578G>T p.V860L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EGF | c.3386C>T p.T1129I | Missense Mutation (SNP) | VAF 131/293 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- EML3 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- FTH1 | c.182_183del p.H61Rfs*7 | Frame Shift Del (DEL) | VAF 140/367 reads (38%) | called by mutect2, pindel, varscan2
- GEMIN5 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- GK2 | c.1333C>A p.P445T | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- GPS1 | c.36G>A p.G12= | Splice Region (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- GRM6 | c.1844T>C p.I615T | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- LAMA3 | c.9368G>C p.S3123T (on ENST00000313654 / NM_198129.4; = p.S1514T on NM_000227.6) | Missense Mutation (SNP) | VAF 136/234 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDB1 | c.526_528del p.V176del (on ENST00000425280 / NM_001321612.2; = p.V140del on NM_003893.5) | In Frame Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- LPCAT4 | c.761G>A p.W254* | Nonsense Mutation (SNP) | VAF 76/139 reads (55%) | called by muse, mutect2, varscan2
- MIDEAS | c.2163-2del p.X721_splice | Splice Site (DEL) | VAF 33/154 reads (21%) | called by mutect2, pindel, varscan2
- MUC22 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.25); called by mutect2, varscan2
- NOVA2 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OXCT1 | c.613_620del p.G205Cfs*39 | Frame Shift Del (DEL) | VAF 82/304 reads (27%) | called by mutect2, varscan2
- PDE1A | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SLC45A1 | c.1606T>C p.S536P | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SLC4A5 | c.2292C>G p.F764L | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SOX9 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 130/314 reads (41%) | called by muse, mutect2, varscan2
- SOX9 | c.1331_1332dup p.H445Tfs*26 | Frame Shift Ins (INS) | VAF 91/280 reads (33%) | called by mutect2, pindel, varscan2
- TNIK | c.3731T>C p.V1244A | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- TTC17 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- TUBA4A | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 86/550 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13C | c.2312G>T p.R771L (on ENST00000644861 / NM_020821.3; = p.R728L on NM_017684.5) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- WWC2 | c.2215dup p.R739Kfs*10 | Frame Shift Ins (INS) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- ZBTB47 | c.1273G>T p.G425W | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ZNF84 | c.1932T>G p.N644K | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZPBP2 | c.789G>A p.M263I (on ENST00000348931 / NM_199321.3; = p.M241I on NM_198844.3) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AATK | c.2862G>A p.A954= (on ENST00000326724 / NM_001080395.3; = p.A851= on NM_004920.2) | Silent (SNP) | VAF 130/322 reads (40%) | catalogued as rs756790781, COSV58373321; called by muse, varscan2
- ACSS3 | c.948C>T p.Y316= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs188026796; called by muse, mutect2, varscan2
- ASPM | c.3678C>T p.D1226= | Silent (SNP) | VAF 39/277 reads (14%) | called by muse, mutect2, varscan2
- COL18A1 | c.2802C>T p.A934= (on ENST00000359759 / NM_130444.3; = p.A699= on NM_030582.4) | Silent (SNP) | VAF 140/565 reads (25%) | catalogued as rs372703675; called by muse, mutect2, varscan2
- CRLF2 | c.453G>A p.Q151= | Silent (SNP) | VAF 29/182 reads (16%) | called by muse, mutect2, varscan2
- EML6 | c.948G>A p.P316= | Silent (SNP) | VAF 69/489 reads (14%) | catalogued as rs986035591; called by muse, varscan2
- FBXO25 | c.333C>T p.D111= (on ENST00000382824 / NM_183421.2; = p.D44= on NM_012173.3) | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- GEMIN2 | c.157C>T p.L53= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- GOLGB1 | c.4671G>A p.R1557= | Silent (SNP) | VAF 47/140 reads (34%) | called by muse, mutect2, varscan2
- GPR89B | c.12G>C p.L4= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as rs7552095; called by muse, mutect2, varscan2
- H2BC12 | c.30G>T p.A10= | Silent (SNP) | VAF 19/139 reads (14%) | called by muse, mutect2, varscan2
- HTRA3 | c.492G>A p.P164= | Silent (SNP) | VAF 71/151 reads (47%) | catalogued as rs149150956, COSV56470538; called by muse, mutect2, varscan2
- IGFL1 | c.69C>T p.H23= | Silent (SNP) | VAF 82/172 reads (48%) | catalogued as rs758857747, COSV71443709; called by muse, mutect2, varscan2
- KHDC1 | c.375C>T p.H125= (on ENST00000370384 / NM_001251874.2; = p.H52= on NM_030568.5) | Silent (SNP) | VAF 23/139 reads (17%) | called by muse, mutect2, varscan2
- MYO15B | c.3678T>A p.P1226= | Silent (SNP) | VAF 48/132 reads (36%) | called by mutect2, varscan2
- NBEAL2 | c.2523C>T p.L841= | Silent (SNP) | VAF 92/413 reads (22%) | catalogued as rs770761759; called by muse, mutect2, varscan2
- NFYB | c.213C>T p.A71= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs1315363842; called by muse, mutect2, varscan2
- NIPAL1 | c.273G>A p.K91= | Silent (SNP) | VAF 35/158 reads (22%) | catalogued as rs779125775; called by muse, mutect2, varscan2
- OGT | c.2733C>T p.H911= | Silent (SNP) | VAF 139/170 reads (82%) | catalogued as rs767137965; called by muse, mutect2, varscan2
- PCDH17 | c.1542G>A p.S514= | Silent (SNP) | VAF 73/432 reads (17%) | catalogued as rs976333418; called by muse, mutect2, varscan2
- PCDHA3 | c.1449C>T p.D483= | Silent (SNP) | VAF 214/810 reads (26%) | catalogued as COSV63542712; called by muse, varscan2
- PCDHB6 | c.594G>A p.P198= | Silent (SNP) | VAF 99/224 reads (44%) | catalogued as rs782776876, COSV99171168; called by muse, mutect2, varscan2
- PIGC | c.280C>T p.L94= | Silent (SNP) | VAF 40/186 reads (22%) | called by muse, mutect2, varscan2
- PLA2G15 | c.1104C>T p.A368= | Silent (SNP) | VAF 208/550 reads (38%) | called by muse, mutect2, varscan2
- PLXNA3 | c.3927G>A p.P1309= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as rs202128522, COSV63754528; called by muse, mutect2, varscan2
- PRKCE | c.168C>T p.T56= | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as COSV100076531; called by muse, mutect2, varscan2
- SH2D5 | c.1008G>A p.T336= (on ENST00000444387 / NM_001103161.2; = p.T252= on NM_001103160.2) | Silent (SNP) | VAF 71/131 reads (54%) | catalogued as rs745620710; called by muse, mutect2, varscan2
- SIAH1 | c.783C>T p.T261= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- STK11IP | c.2220G>A p.P740= | Silent (SNP) | VAF 410/687 reads (60%) | catalogued as rs567009609, COSV55245330; called by mutect2, varscan2
- TMEM249 | c.582C>T p.F194= | Silent (SNP) | VAF 25/218 reads (11%) | catalogued as rs1554852010; called by muse, mutect2, varscan2
- TNC | c.2871G>A p.P957= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs369296365; called by muse, mutect2, varscan2
- TNFSF9 | c.591C>T p.F197= | Silent (SNP) | VAF 53/219 reads (24%) | catalogued as rs375425240, COSV55538150, COSV55538733; called by muse, mutect2, varscan2
- TNR | c.3663G>A p.Q1221= | Silent (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- UBE2J2 | c.489C>T p.V163= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as rs906399652, COSV100231118; called by muse, mutect2, varscan2
- VARS2 | c.1917G>A p.Q639= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV58913917; called by muse, mutect2, varscan2
- WNK2 | c.1647G>A p.A549= | Silent (SNP) | VAF 127/224 reads (57%) | catalogued as rs750657954; called by muse, mutect2, varscan2
- YAF2 | c.327T>C p.D109= | Silent (SNP) | VAF 14/49 reads (29%) | called by mutect2, varscan2
- ZMYM5 | c.1887C>T p.V629= | Silent (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
- ZNF444 | c.825G>A p.A275= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs1461249655, COSV61364025; called by muse, mutect2, varscan2
- ARMC5 | chr16:31458956 A>G | 5'Flank (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- BET1-AS1 | n.225+6331C>T | Intron (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- BRD9 | c.966+524_966+525del | Intron (DEL) | VAF 24/128 reads (19%) | catalogued as rs1448013543; called by pindel, varscan2
- C19orf38 | c.-28C>T | 5'UTR (SNP) | VAF 27/136 reads (20%) | catalogued as rs548441287, COSV101186731; called by muse, mutect2, varscan2
- CABIN1 | c.4117+19C>T | Intron (SNP) | VAF 78/373 reads (21%) | called by muse, mutect2, varscan2
- CRHR2 | c.-41G>A | 5'UTR (SNP) | VAF 9/58 reads (16%) | catalogued as rs750371411; called by muse, mutect2, varscan2
- CTTN | c.902-380G>A | Intron (SNP) | VAF 44/180 reads (24%) | catalogued as rs1191200028; called by muse, mutect2, varscan2
- DEFB4B | c.*29C>T | 3'UTR (SNP) | VAF 30/134 reads (22%) | catalogued as rs763532707; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446486 G>A | 3'Flank (SNP) | VAF 75/517 reads (15%) | catalogued as rs763959782; called by muse, mutect2, varscan2
- IGF2BP2 | c.240-23886G>A | Intron (SNP) | VAF 35/87 reads (40%) | catalogued as rs962163656; called by muse, mutect2, varscan2
- PCDHA5 | c.2352+77del | Intron (DEL) | VAF 22/90 reads (24%) | catalogued as rs781996539; called by mutect2, varscan2
- TEX261 | c.70+55T>C | Intron (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- TMEM186 | c.-8G>A | 5'UTR (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- VIP | c.*26G>T | 3'UTR (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- Z82190.2 | c.1787-21737C>A | Intron (SNP) | VAF 6/130 reads (5%) | catalogued as COSV50735165; called by muse, mutect2
